TCGA case TCGA-VQ-A8PM — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Stomach; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bab53c56-82f1-4d63-98f5-4608ea7b5f4e

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 56 years; Vital status: Dead; Days to death: 57 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Signet ring cell carcinoma: ICD-O-3 morphology code: 8490/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 56.6 years (20,665 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 55; Lymph nodes tested: 81.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 57 days; Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VQ-A8PM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 220 mg.
  Slide TCGA-VQ-A8PM-01A-02-TS2: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 4; Percent necrosis: 10; Percent stromal cells: 16; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 4.
- Sample TCGA-VQ-A8PM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VQ-A8PM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach Adenocarcinoma, Signet Ring Type; Cause of death: Other, non-malignant disease; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Cardia/Proximal; Lymph nodes examined: Yes; Tumor sample procurement country: Sao Paulo; Cancer procurement city: Barretos; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 57 days; disease-specific survival: no event (censored), 57 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 57 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VQ-A8PM-01A-21D-A40Z-01): tumor purity 0.3, ploidy 1.79, whole-genome doublings 0.
